Surgical pathology report (de-identified scan), TCGA case TCGA-23-2077, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-2077-01A (Primary Tumor).

[page 1 of 4]
PATH #:

A/S:

Rec:

Col:

Pathologist:

Assistant:

Attending MD:

Ordering MD:

Copies To:

TCGA-23-2077

=====

DIAGNOSIS:

- 1: LEFT OVARY AND FROZEN SECTION:
- Serous carcinoma with focal papillary and clear cell features
- Nuclear grade 3/3
- Focal necrosis and psammoma bodies are present
- Tumor involves entire ovary
- No definitive lymphatic invasion is identified
- Capsular invasion is present
- 2: RIGHT OVARY:
- Serous carcinoma
- Nuclear grade 3
- No definitive lymphatic invasion identified
- 80% of ovary involved with focal necrosis and capsular invasion
- Fallopian tube without evidence of tumor
- 3: UTERUS AND CERVIX:
- Proliferative endometrium
- Uterine leiomyoma
- Cervix with Nabothian cysts
- Negative for malignancy
- 4: OMENTUM NO.1:
- Omentum with focal lymphocytic aggregates and mesothelial hyperplasia
- Negative for malignancy
- 5: OMENTUM NO.2:
- Omentum with lymphocytes and mesothelial hyperplasia
- Benign lymph node
- Negative for malignancy
- 6: OMENTUM NO.3:
- Scattered clusters of malignant cells consistent with ovarian primary, fat necrosis, acute inflammation, calcifications, granulation tissue and hemosiderin-laden macrophages
- 7: ILEUM ADHESION BIOPSY:
- Fat and fibrous tissue with acute and chronic inflammation, and numerous macrophages
- Negative for malignancy

[page 2 of 4]
8: LIVER BIOPSY:

- Portal tract lymphocytic infiltrates and venous dilatation in subcapsular liver specimen
- Negative for malignancy

9: APPENDIX:

- Appendix without histopathologic abnormalities
- Negative for malignancy

COMMENT: [REDACTED] has reviewed the slides and agrees.

HISTORY: Possible ovarian cancer, metastasis to the chest

MICROSCOPIC:
See Diagnosis.

GROSS:

1: LEFT OVARY AND FROZEN SECTION

Labeled "left ovary and frozen section", received fresh partially utilized for frozen section and subsequently placed in formalin, is a 580 gram greatly enlarged bosselated tan-pink, hemorrhagic ovary measuring 13.0 x 12.5 x 6.0 cm. The surface of the ovary has focal tan-yellow discoloration along with several cystic structures filled with clear serous fluid ranging in size from 0.5 to 2.0 cm in greatest dimension. On section the ovary is obliterated by a solid friable tan mass. Several cystic spaces are present throughout the mass ranging in size from 0.5 to 4.0 cm in greatest dimension. A large amount of hemorrhage and necrosis are present throughout the mass along with focal areas of yellow-tan discoloration. No normal ovarian parenchyma is grossly identified. The mass grossly invades the capsule of the ovary. Representative sections.

A-C. Ovarian lesion - 2 each

2: RIGHT OVARY

Labeled "right ovary" and received in formalin is cystically enlarged ovary with attached fallopian tube measuring 6.0 x 5.0 x 2.5 cm. The segment of fallopian tube measures 4.0 cm in length x 0.8 x 0.7 cm. The fimbriated end is edematous, unremarkable. On sectioning of the fallopian tube no discrete lesions are identified. Multiple edematous tan-pink, soft tissue adhesions are present between the fallopian tube and ovary. The ovary is tan-grey, 4.8 x 3.7 x 2.2 cm. On section a solid tan-pink friable mass is present within the ovary. The mass measures 3.0 x 3.0 x 2.0 cm. It has focal areas of tan-yellow discoloration, necrosis and hemorrhage. The mass composes approximately 80% of the ovary. The remaining 20% of the ovary shows normal ovarian parenchyma with several corpus luteum identified. A focal area of the mass appears to invade the capsule of the ovary. Representative sections.

D. Ovarian mass - 2

E. Mass with normal ovary and fallopian tube - 3

3: UTERUS AND CERVIX

Labeled "uterus and cervix" and consists of a uterus with attached cervix weighing 80 grams. The uterus measures 4.4 x 5.0 x 3.0 cm. The serosa is tan-pink with a minimal amount of hemorrhagic tan-pink, soft tissue adhesions. On section of the myometrium a spherical white-tan myoma is present along the left anterior lower uterine segment measuring 0.4 x 0.4 x 0.4 cm. The mass is composed of whorled white-tan, firm, soft tissue. On opening the endometrial cavity measures 2.2 cm in width x 3.6 cm in greatest length. The

[page 3 of 4]
[REDACTED]

endometrium is tan-pink, diffusely hemorrhagic measuring 0.1 cm in thickness. The cervix measures 4.5 x 4.2 x 4.1 cm. The os measures 1.2 x 0.1 cm and is slit-like. The ectocervix is tan-pink smooth and glistening with bulges along the anterior external os due to underlying nabothian cysts. On opening the endocervical canal measures 3.5 cm in length. The transformation zone is well delineated. Representative sections.

- F. Anterior cervix - 1
- G. Posterior cervix - 1
- H. Anterior endometrium along with myoma - 2
- I. Posterior myometrium and endometrium - 2

4: OMENTUM NO.1

Labeled "omentum #1" and received in formalin is a portion of tan-yellow omentum measuring 11.0 x 4.2 x 1.3 cm. On sectioning the specimen is composed mainly of mature lobulated adipose tissue with fine vessels. No nodules are identified. Representative sections.

J. 2

5: OMENTUM NO.2

Labeled "omentum #2" and consists of a portion of tan-yellow omentum measuring 15.0 x 3.5 x 1.0 cm. On sectioning a firm, tan-white well-circumscribed nodule is identified measuring 0.7 x 0.6 x 0.5 cm. The remaining tissue is composed of mature lobulated adipose tissue with fine vessels. No other discrete nodules are identified. Representative sections.

K. 3

6: OMENTUM NO.3

Labeled "omentum #3" and received in formalin is a portion of tan-yellow omentum measuring 12.5 x 4.5 x 1.2 cm. On serial section a 0.7 x 0.6 x 0.3 cm pale tan nodule is identified. The remaining tissue is composed mainly of mature lobulated adipose tissue with fine vessels. No other discrete lesions are identified. Representative sections.

L. 3

7: ILEUM ADHESION BIOPSY

Labeled "ileum adhesion biopsy" and received in formalin is an irregular fragment of tan-pink soft tissue measuring 0.8 x 0.3 x 0.1 cm. Entirely submitted.

M. 1

8: LIVER BIOPSY

Labeled "liver biopsy" and received in formalin is an irregular fragment of tan-yellow soft tissue measuring 1.8 x 1.4 x 1.0 cm. A portion of hemorrhagic tan-pink capsule is present on the specimen. The margin is entirely inked blue. On serial section the tissue is severely cauterized no discrete nodules are identified. Entirely submitted.

N. 3

9: APPENDIX

Labeled "appendix" and received in formalin is an appendix with attached mesoappendix. The appendix measures 5.4 cm in length x 0.6 cm in diameter. The attached mesoappendix measures 3.5 x 1.4 x 0.6 cm. The serosa is tan-pink, slightly granular with no discrete areas of lesions or perforations identified. On section the wall of the appendix is tan-pink, 0.2 cm in thickness. The lumen measures 0.2 cm

[page 4 of 4]
FS 1: High grade adenoma. No mucinous component seen

Source: NCI Genomic Data Commons file a789b15b-998c-473c-9898-a38950c5f972 (TCGA-23-2077.55589297-F28E-422C-BEEE-6CB19A2350BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).